Gene-level copy-number profile of tumor specimen TCGA-BR-A4PE-01A from TCGA case TCGA-BR-A4PE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.4 years (24,986 days).
Specimen TCGA-BR-A4PE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5e54129f-b9f3-4f8a-8f2d-70cb4b072a24.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4PE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6eb809c2-6d59-413f-80ad-a5730338900c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 289; copy number 2: 11,738; copy number 3: 23,463; copy number 4: 16,422; copy number 5: 4,596; copy number 6: 2,016; copy number 7: 446; copy number 8: 306; copy number 9: 119; copy number 10: 43; copy number 12: 332; copy number 37: 26; copy number 72: 7; copy number 77: 3; copy number 83: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4PE-01A-31D-A253-01): tumor purity 0.55, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,296 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,587,288–34,696,859, 1 gene, copy number 9 (within-gene range 6–9): ILRUN.
- chr6:34,685,355–35,556,264, 29 genes, copy number 9: RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11, SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6, PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3.
- chr6:65,302,522–65,304,957, 1 gene, copy number 7: AL365217.1.
- chr6:73,693,903–80,557,189, 89 genes, copy number 9 (broad region; genes not listed).
- chr7:91,692,008–99,207,506, 138 genes, copy number 8 (broad region; genes not listed).
- chr8:5,072,645–23,425,328, 475 genes, copy number 8–12 (within-gene range 5–12) (broad region; genes not listed).
- chr8:117,265,272–130,655,712, 199 genes, copy number 7 (broad region; genes not listed).
- chr9:25,937,912–36,304,924, 246 genes, copy number 7 (broad region; genes not listed).
- chr9:71,589,601–73,170,393, 25 genes, copy number 8: RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1.
- chr17:19,215,615–19,336,715, 1 gene, copy number 10 (within-gene range 2–10): EPN2.
- chr17:19,296,596–19,897,287, 41 genes, copy number 10: EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1.
- chr17:39,665,349–39,864,312, 8 genes, copy number 10–72 (within-gene range 5–72): TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:41,500,981–41,865,423, 24 genes, copy number 37 (within-gene range 4–37): KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11.
- chr17:50,962,174–52,160,017, 16 genes, copy number 37–83 (within-gene range 4–83): SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1.
- chr17:68,591,796–68,797,822, 3 genes, copy number 77: LINC01482, AC011591.2, AC011591.1.

Autosomal genes at a single copy (total copy number 1): 289. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
